TARGET case TARGET-30-PAPSKM — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ef1b0f3e-77d7-5e0a-9112-e6d7334b6fce

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Dead; Days to death: 1,019 days (2.8 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 3.6 years (1,330 days); Year of diagnosis: 2006; Days to last follow up: 1,019 days (2.8 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: High.
   Pathology details: Necrosis percent: 0; Percent tumor nuclei: 100.
   Treatment given: Protocol identifier: ANBL0421.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (3 entries)
- Days to follow up: 573 days (1.6 years); Progression or recurrence anatomic site: Bone, NOS; Days to first event: 573 days (1.6 years); First event: Relapse.
- Days to follow up: 573 days (1.6 years); Progression or recurrence anatomic site: Bone marrow.
- Days to follow up: 1,019 days (2.8 years); Year of follow up: 2009.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAPSKM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPSKM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1019
- Protocol: ANBL00B1, ANBL0421
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.4
- Histology: Unfavorable
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Percent Necrosis: 0
- Percent Tumor v/s Stroma: 100/0
- Site of Relapse: Bone; Bone Marrow
